Gene-level copy-number profile of specimen HCM-BROD-0125-C25-85B from HCMI case HCM-BROD-0125-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 72.9 years (26,629 days).
Specimen HCM-BROD-0125-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2bd55fe2-16b2-4d6b-8174-b2a03a716bb8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0125-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/18b0f796-e886-436d-af8c-6924ac80907e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 366; copy number 1: 3,174; copy number 2: 12,577; copy number 3: 21,161; copy number 4: 17,788; copy number 5: 3,051; copy number 6: 635; copy number 7: 128; copy number 8: 19; copy number 9: 9; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:1,328,664–3,691,814, 22 genes: AL358934.1, RNA5SP279, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1.
- chr9:14,204,248–14,205,039, 1 gene (within-gene range 0–4): AL441963.1.
- chr9:21,638,285–23,438,700, 23 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:23,632,106–23,632,360, 1 gene: SUMO2P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 157 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–2,967,955, 83 genes, copy number 7 (broad region; genes not listed).
- chr6:29,934,101–29,934,286, 1 gene, copy number 7: HLA-U.
- chr8:38,105,493–38,468,834, 21 genes, copy number 7–9: ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22.
- chr9:37,046,835–38,068,687, 28 genes, copy number 7–8 (within-gene range 2–8): AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA, RNU6-677P, LINC01627, GRHPR, CHCHD4P3, ZBTB5, KCTD9P3, POLR1E, AL158156.1, AL513165.1, FBXO10, AL513165.2, TOMM5, AL138752.2, RAB1C, FRMPD1, RN7SKP171, TRMT10B, EXOSC3, DCAF10.
- chr9:37,915,898–38,069,227, 1 gene, copy number 8 (within-gene range 2–8): SHB.
- chr9:72,007,881–72,008,136, 1 gene, copy number 7: HSPB1P1.
- chr12:39,466,442–39,619,803, 4 genes, copy number 7–8: AC121334.1, AC121334.2, ABCD2, AC121334.3.
- chr12:39,755,025–40,106,089, 3 genes, copy number 7 (within-gene range 6–7): SLC2A13, AC121336.1, RPL30P13.
- chr12:40,196,744–40,369,285, 2 genes, copy number 7 (within-gene range 6–7): LRRK2, AC084290.1.
- chr12:41,188,320–41,574,745, 2 genes, copy number 7: PDZRN4, AC090531.1.
- chr12:49,184,795–49,324,576, 7 genes, copy number 7 (within-gene range 4–7): TUBA1A, TUBA1C, Metazoa_SRP, AC010173.1, AC125611.3, AC125611.4, PRPH.
- chr18:24,162,045–24,397,880, 1 gene, copy number 7 (within-gene range 4–12): OSBPL1A.
- chr18:24,321,686–24,402,714, 3 genes, copy number 7–12: MIR320C2, AC023983.1, AC023983.2.

Autosomal genes at a single copy (total copy number 1): 858. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
